Somatic mutation profile of tumor specimen HCM-SANG-0314-C15-01A (aliquot HCM-SANG-0314-C15-01A-01D-A79N-36) from HCMI case HCM-SANG-0314-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0314-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c77da63-f0ff-474c-9ba5-74f2f3c6ae81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0314-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0314-C15-10A-01D-A79N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9984495-a101-4d58-896a-0f2e1bad4ff3

The open-access MAF lists 129 somatic variants for this specimen: 101 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 26, Nonsense Mutation 4, Intron 2, In Frame Del 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 119/290 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 18/523 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV59388871; called by muse, mutect2
- ABCC12 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762026626, COSV100252717, COSV100253108; called by muse, mutect2, varscan2
- ABCC8 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 52/700 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs773168707; called by muse, mutect2
- AMER1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1213657177; called by muse, mutect2
- ARID2 | c.551C>G p.S184* | Nonsense Mutation (SNP) | VAF 124/378 reads (33%) | catalogued as COSV57600529, COSV57604556; called by muse, mutect2, varscan2
- ARID5A | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 168/608 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs368122000; called by muse, mutect2, varscan2
- ATP1A3 | c.1174G>A p.A392T (on ENST00000545399 / NM_001256214.2; = p.A379T on NM_152296.5) | Missense Mutation (SNP) | VAF 113/495 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV57488799; called by muse, mutect2, varscan2
- C8B | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 31/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs955479183, COSV100980703, COSV64777175; called by muse, mutect2
- C9orf16 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 192/610 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs760211969; called by muse, mutect2, varscan2
- CCKAR | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 106/521 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55161754; called by muse, mutect2, varscan2
- CDH9 | c.487T>G p.L163V | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50253829, COSV99145286, COSV99163241; called by muse, mutect2, varscan2
- CNTLN | c.2813A>C p.K938T | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52093458, COSV99262418; called by muse, varscan2
- COL4A1 | c.4832C>T p.A1611V | Missense Mutation (SNP) | VAF 288/663 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs775233741, COSV65423218, COSV65434312; called by muse, mutect2, varscan2
- CPB2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 50/512 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs745915460, COSV51675401, COSV51676445; called by muse, mutect2
- CPXM2 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 146/484 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs770522746, COSV53860400; called by muse, mutect2, varscan2
- CREBZF | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 182/644 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1415613126; called by muse, mutect2, varscan2
- DNTTIP2 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756513922, COSV63283920; called by muse, mutect2, varscan2
- DOCK3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 129/389 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs756421617, COSV56539986; called by muse, mutect2, varscan2
- EMC1 | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 77/329 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146583625; called by muse, mutect2, varscan2
- EPHA6 | c.2721A>C p.K907N (on ENST00000389672 / NM_001080448.3; = p.K299N on NM_173655.4) | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs761211944, COSV101063569, COSV67588567; called by muse, mutect2
- ERICH3 | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58614605; called by muse, mutect2, varscan2
- EXT1 | c.1836G>C p.W612C | Missense Mutation (SNP) | VAF 239/496 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as CM099181, COSV65478653; called by muse, mutect2, varscan2
- FAM81A | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55680254; called by muse, mutect2
- FLNC | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 48/849 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs754309921, COSV57953861; ClinVar: uncertain significance; called by muse, mutect2
- HMBOX1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55066470; called by muse, mutect2, varscan2
- IGHE | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 148/459 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.877); catalogued as rs782083953; called by muse, mutect2, varscan2
- IL12B | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 145/402 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as COSV104370863; called by muse, varscan2
- KRT34 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 208/687 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs200232759; called by muse, mutect2, varscan2
- KSR2 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 107/422 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs747557790, COSV56672047; called by muse, varscan2
- MDH1B | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 123/418 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs779426389, COSV65588397; called by muse, mutect2, varscan2
- MEPE | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 212/479 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755462303; called by muse, mutect2, varscan2
- MYH15 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs201981854; called by muse, varscan2
- NEB | c.13763G>A p.R4588Q | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs575958060, COSV50890065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.3888T>G p.Y1296* | Nonsense Mutation (SNP) | VAF 18/266 reads (7%) | catalogued as CM1311470, CM1411390; called by muse, mutect2
- OR51G1 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 102/418 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100429398; called by muse, mutect2, varscan2
- PABPC4L | c.1056G>T p.M352I | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69931176, COSV99081465; called by muse, mutect2, varscan2
- PCDH11Y | c.2988A>C p.Q996H (on ENST00000400457 / NM_032973.2; = p.Q985H on NM_032971.3) | Missense Mutation (SNP) | VAF 13/426 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99292334; called by muse, mutect2
- PCDHA3 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 172/363 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65364216; called by muse, mutect2, varscan2
- PCDHB13 | c.2036C>T p.T679I | Missense Mutation (SNP) | VAF 24/768 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs376242901, COSV99507936; called by muse, mutect2
- PCDHB6 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 337/677 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV50699885; called by muse, mutect2, varscan2
- PDZRN4 | c.1799T>G p.L600R (on ENST00000402685 / NM_001164595.2; = p.L342R on NM_013377.4) | Missense Mutation (SNP) | VAF 19/332 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV54196850; called by muse, mutect2
- PLA2G7 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 88/281 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs767724546, COSV51258335; called by muse, mutect2, varscan2
- PPP1R42 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 53/221 reads (24%) | catalogued as rs909819876; called by muse, mutect2, varscan2
- PTPRT | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 111/653 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61986719; called by muse, mutect2, varscan2
- RIMS2 | c.3164G>A p.R1055H (on ENST00000666250 / NM_001348490.2; = p.R863H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 200/503 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs199562210, COSV51667384; called by muse, mutect2, varscan2
- SDK1 | c.4487G>A p.R1496Q | Missense Mutation (SNP) | VAF 364/835 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs141114121; called by muse, mutect2, varscan2
- SEMA5A | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751530635, COSV66784394; called by muse, mutect2, varscan2
- SFMBT2 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 146/505 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs748712257, COSV62805508; called by muse, mutect2, varscan2
- SLC6A1 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 82/354 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs767142926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SORCS3 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV63806753, COSV99056408; called by muse, mutect2, varscan2
- SP3 | c.72_83del p.G26_G29del | In Frame Del (DEL) | VAF 136/656 reads (21%) | catalogued as rs759652858; called by mutect2, varscan2
- TEKT4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 227/832 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs782558219, COSV54626009; called by muse, mutect2, varscan2
- TMEM266 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 201/674 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.02); catalogued as rs763774429; called by muse, mutect2, varscan2
- TSNAXIP1 | c.989_991del p.V330del | In Frame Del (DEL) | VAF 94/358 reads (26%) | catalogued as rs764966774; called by pindel, varscan2
- UNC80 | c.4345G>A p.A1449T | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs553977942; called by muse, mutect2, varscan2
- ZFHX4 | c.9839G>T p.G3280V | Missense Mutation (SNP) | VAF 270/593 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV50701146, COSV51468983; called by muse, mutect2, varscan2
- ABCC9 | c.2230A>C p.T744P | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ANKRD33B | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 67/956 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2
- ARID2 | c.5371_5372del p.K1791Efs*3 | Frame Shift Del (DEL) | VAF 47/187 reads (25%) | called by mutect2, pindel, varscan2
- ASIC5 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 111/482 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATMIN | c.444G>C p.Q148H | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN2 | c.3202C>T p.P1068S (on ENST00000550104; = p.P908S on NM_002973.4) | Missense Mutation (SNP) | VAF 18/387 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATXN3 | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 68/341 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by mutect2, varscan2
- BACH2 | c.1577A>G p.Y526C | Missense Mutation (SNP) | VAF 60/598 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- C2orf16 | c.4108G>A p.V1370M | Missense Mutation (SNP) | VAF 92/314 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCDC88B | c.2538G>T p.M846I | Missense Mutation (SNP) | VAF 29/575 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- CHIA | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.339); called by muse, varscan2
- CORO1A | c.1215G>C p.R405S | Missense Mutation (SNP) | VAF 146/469 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DENND2C | c.1088A>C p.K363T | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM171B | c.2287A>C p.I763L | Missense Mutation (SNP) | VAF 100/390 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- FLRT2 | c.455A>G p.D152G | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2
- GUCY1B1 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 46/600 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2
- IL7 | c.271T>G p.F91V | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2
- IQCM | c.1137T>G p.I379M | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- LMBRD2 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); called by muse, mutect2
- LOXHD1 | c.4516T>A p.F1506I | Missense Mutation (SNP) | VAF 90/364 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LSG1 | c.266C>A p.T89N | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- MAPK8 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.43); called by muse, mutect2
- MPO | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYOD1 | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 104/410 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- OSBPL2 | c.316C>T p.R106W (on ENST00000313733 / NM_144498.4; = p.R94W on NM_014835.4) | Missense Mutation (SNP) | VAF 123/789 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL5 | c.1245G>C p.R415S | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- OSBPL8 | c.464T>G p.L155* | Nonsense Mutation (SNP) | VAF 91/291 reads (31%) | called by muse, mutect2, varscan2
- PCDH17 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 49/1027 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- POP1 | c.2081A>C p.N694T | Missense Mutation (SNP) | VAF 75/337 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTCHD3 | c.2192A>T p.N731I | Missense Mutation (SNP) | VAF 99/322 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RIMS1 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 42/642 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- SETBP1 | c.1097A>G p.E366G | Missense Mutation (SNP) | VAF 113/360 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- SLITRK2 | c.56C>A p.T19K | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- STOML3 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 235/528 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TENM3 | c.3079_3080insG p.I1027Sfs*4 | Frame Shift Ins (INS) | VAF 157/466 reads (34%) | called by mutect2, pindel, varscan2
- TENM4 | c.1103T>A p.L368Q | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM229A | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 343/662 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRBV20OR9-2 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 114/391 reads (29%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- TRIM67 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 196/923 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- UBR5 | c.7685A>G p.K2562R | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- USP42 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 80/396 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ZNF197 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 35/353 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- ZNF792 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 24/559 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF837 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 44/938 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); called by muse, mutect2
- ANOS1 | c.1932G>A p.P644= | Silent (SNP) | VAF 177/317 reads (56%) | catalogued as rs199652310; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP42 | c.2193A>G p.K731= | Silent (SNP) | VAF 59/239 reads (25%) | called by muse, mutect2
- CGB2 | c.234C>T p.R78= | Silent (SNP) | VAF 60/1050 reads (6%) | catalogued as rs766320454; called by muse, varscan2
- CNTN1 | c.744C>T p.F248= | Silent (SNP) | VAF 67/234 reads (29%) | called by muse, mutect2, varscan2
- COL5A1 | c.1074C>T p.G358= | Silent (SNP) | VAF 117/494 reads (24%) | catalogued as rs561440698, COSV65670739; ClinVar: likely benign; called by muse, mutect2, varscan2
- DACT1 | c.1209C>T p.G403= | Silent (SNP) | VAF 128/432 reads (30%) | catalogued as rs1174468297; called by muse, mutect2, varscan2
- FAM120A | c.1800G>C p.L600= | Silent (SNP) | VAF 110/422 reads (26%) | called by muse, mutect2, varscan2
- GOLGA3 | c.843G>A p.A281= | Silent (SNP) | VAF 145/519 reads (28%) | catalogued as rs1240328220, COSV52640767; called by muse, mutect2, varscan2
- GPR158 | c.1488C>T p.Y496= | Silent (SNP) | VAF 82/282 reads (29%) | catalogued as rs150342987; called by muse, mutect2, varscan2
- MARF1 | c.5145C>T p.P1715= | Silent (SNP) | VAF 34/539 reads (6%) | catalogued as rs778124218, COSV60025055; called by muse, mutect2
- MDGA2 | c.1407A>G p.T469= (on ENST00000399232 / NM_001113498.2; = p.T171= on NM_182830.4) | Silent (SNP) | VAF 127/430 reads (30%) | catalogued as COSV100637274; called by muse, mutect2, varscan2
- NRBF2 | c.96T>A p.S32= | Silent (SNP) | VAF 24/426 reads (6%) | called by muse, mutect2
- NXPH1 | c.294A>G p.Q98= | Silent (SNP) | VAF 40/572 reads (7%) | catalogued as rs369902603; called by muse, mutect2
- OOSP1 | c.342G>A p.S114= | Silent (SNP) | VAF 58/248 reads (23%) | catalogued as rs545086371; called by muse, mutect2, varscan2
- OR4K2 | c.564T>G p.A188= | Silent (SNP) | VAF 59/466 reads (13%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.903T>G p.T301= | Silent (SNP) | VAF 120/331 reads (36%) | called by muse, mutect2, varscan2
- RCN2 | c.93G>T p.P31= | Silent (SNP) | VAF 24/724 reads (3%) | called by muse, mutect2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 34/501 reads (7%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2
- SERTAD2 | c.366C>T p.S122= | Silent (SNP) | VAF 21/689 reads (3%) | catalogued as rs1004166678; called by muse, mutect2
- SORL1 | c.4569C>T p.D1523= | Silent (SNP) | VAF 62/337 reads (18%) | catalogued as rs765220891, COSV52760273; called by muse, mutect2, varscan2
- SUSD1 | c.570C>A p.I190= | Silent (SNP) | VAF 95/347 reads (27%) | catalogued as rs889595102; called by muse, mutect2, varscan2
- TGM4 | c.843G>A p.A281= | Silent (SNP) | VAF 29/263 reads (11%) | catalogued as rs147739675; called by muse, mutect2, varscan2
- TRIM28 | c.681C>T p.L227= | Silent (SNP) | VAF 239/621 reads (38%) | called by muse, mutect2, varscan2
- TRO | c.3000C>T p.G1000= | Silent (SNP) | VAF 145/261 reads (56%) | catalogued as rs771217762, COSV99435803; called by muse, mutect2, varscan2
- ZC3HAV1L | c.846G>A p.L282= | Silent (SNP) | VAF 187/550 reads (34%) | called by muse, mutect2, varscan2
- ZNF391 | c.435T>G p.S145= | Silent (SNP) | VAF 68/535 reads (13%) | called by muse, mutect2, varscan2
- GRIK3 | c.2565+49C>T | Intron (SNP) | VAF 106/536 reads (20%) | catalogued as rs369751433; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-13505T>C | Intron (SNP) | VAF 40/190 reads (21%) | called by muse, mutect2, varscan2
